Gene-level copy-number profile of tumor specimen ALCH-B388-TTP1-A from ALCHEMIST case ALCH-B388, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Pleomorphic carcinoma; Age at diagnosis: 47.7 years (17,411 days).
Specimen ALCH-B388-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7266667e-afa4-4462-abfc-60a47e6020a7.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B388-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,256 have no estimate.
https://portal.gdc.cancer.gov/files/ed90c171-b103-4cc2-b003-537b5922fe7b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 200; copy number 1: 22,966; copy number 2: 32,122; copy number 3: 2,206; copy number 4: 101; copy number 5: 455; copy number 6: 316; copy number 15: 1.

Homozygous deletions (total copy number 0; autosomes only): 195 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,430,539–1,442,882, 2 genes: LINC01770, VWA1.
- chr3:46,364,955–46,485,234, 4 genes: CCR5AS, CCR5, CCRL2, LTF.
- chr3:46,694,528–46,710,886, 1 gene: TMIE.
- chr3:46,719,583–46,736,429, 1 gene (within-gene range 0–2): PRSS46P.
- chr3:50,558,025–50,649,291, 5 genes: C3orf18, HEMK1, AC096920.1, CISH, MAPKAPK3.
- chr3:71,289,769–71,305,853, 1 gene (within-gene range 0–1): FOXP1-AS1.
- chr3:75,521,803–75,522,012, 1 gene: SNRPCP10.
- chr7:151,877,042–151,879,223, 1 gene (within-gene range 0–2): PRKAG2-AS1.
- chr8:12,115,767–12,177,550, 6 genes: FAM66D, AC130366.1, USP17L7, USP17L2, DEFB109D, FAM90A2P.
- chr9:136,322,303–136,359,605, 2 genes (within-gene range 0–1): DKFZP434A062, GPSM1.
- chr9:136,935,840–136,937,988, 2 genes (within-gene range 0–1): AL807752.1, AL807752.5.
- chr10:86,970,741–90,628,852, 91 genes (within-gene range 0–2) (broad region; genes not listed).
- chr11:55,635,113–55,666,195, 3 genes: OR4P4, OR4S2, OR4C6.
- chr14:18,343,038–18,343,144, 1 gene: RNU6-458P.
- chr15:57,319,138–57,325,039, 1 gene: LINC01413.
- chr17:17,810,399–17,837,011, 3 genes (within-gene range 0–2): SREBF1, MIR6777, MIR33B.
- chr19:1,228,287–1,238,027, 1 gene (within-gene range 0–1): CBARP.
- chr20:12,380,056–12,381,255, 1 gene: PA2G4P2.
- chr20:30,214,765–30,214,976, 1 gene: CFTRP3.
- chr21:12,999,676–15,067,837, 62 genes (broad region; genes not listed).
- chr22:46,244,011–46,263,343, 2 genes: CDPF1, PKDREJ.
- chr22:50,245,450–50,307,646, 3 genes (within-gene range 0–1): MAPK12, MAPK11, PLXNB2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 772 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:144,421,386–145,708,148, 34 genes, copy number 6: NBPF15, PFN1P6, AC246785.1, RNVU1-26, RNVU1-2A, RNVU1-28, PPIAL4F, LINC01632, FP700111.1, FP700107.1, RNA5SP59, FP700111.2, FP700111.3, SRGAP2B, AC242498.1, FAM72D, LINC01145, RNU1-153P, AC241585.2, AC241585.1, PPIAL4D, AC245014.2, RNVU1-14, AC245014.3, AC245014.1, NBPF20, PFN1P3, RNU1-154P, RNVU1-31, AC239860.2, AC239860.1, NBPF25P, GPR89A, PDZK1.
- chr1:145,738,868–149,747,818, 134 genes, copy number 6 (within-gene range 1–6) (broad region; genes not listed).
- chr1:149,754,301–161,470,523, 600 genes, copy number 5–6 (broad region; genes not listed).
- chr5:795,606–850,986, 2 genes, copy number 5 (within-gene range 2–5): ZDHHC11, SPCS2P3.
- chr16:46,842,632–46,844,618, 1 gene, copy number 5: CKBP1.
- chr21:43,461,960–43,479,534, 1 gene, copy number 15 (within-gene range 1–15): LINC00313.

Autosomal genes at a single copy (total copy number 1): 22,966. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
